Surgical pathology report (de-identified scan), TCGA case TCGA-24-1928, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1928-01A (Primary Tumor).

[page 1 of 4]
TCGA-24-1928

SURGICAL PATHOLOGY REPORT

Other Related Clinical Data:

DIAGNOSIS: OMENTUM, OMENTECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA

LARGE BOWEL, COLONIC IMPLANT, EXCISION

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA

SMALL BOWEL, IMPLANT, EXCISION

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA

APPENDIX, APPENDECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING PERIAPPENDICEAL SOFT TISSUE

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING SEROSAL SURFACE \T\
PARAOVARIAN SOFT TISSUE
- BRENNER TUMOR, 1.3 CM

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING SEROSAL SURFACE \T\
PARAOVARIAN SOFT TISSUE

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING PERITUBAL SOFT TISSUE

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING PERITUBAL SOFT TISSUE
- PERITUBAL SIMPLE CYSTS
- TUBO-OVARIAN ADHESIONS

[page 2 of 4]
UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- MILD ACUTE \T\ CHRONIC INFLAMMATION

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- CYSTIC ATROPHY

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- MULTIPLE LEIOMYOMAS, LARGEST 0.3 CM

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY
- EXTENSIVE INVOLVEMENT BY POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By [REDACTED]

Microscopic Description and Comment: Poorly differentiated papillary serous adenocarcinoma extensively replaces the omentum, is present on the serosal surfaces of the appendix, uterus, both ovaries and both fallopian tubes and involves the specimens labelled "colonic implant" and "small bowel implant." Both ovaries have been entirely submitted and no significant cortical involvement is identified. The endometrium exhibits cystic atrophy but is free of carcinoma. The myometrium contains several leiomyomas, the largest measuring 0.3 cm. Because the bulk of the tumor is present in the omentum and peritoneal locations and the totally submitted ovaries exhibit only a small amount of tumor on the serosal surfaces, this tumor is best classified as a primary peritoneal papillary serous adenocarcinoma.

History: The patient is a [REDACTED] with a history of breast carcinoma [REDACTED] now has malignant ascites and a pelvic mass. Operative procedure: Examination under anesthesia, exploratory laparotomy, omentectomy, appendectomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy and tumor debulking.

Specimen(s) Received:

- A: OMENTUM
- B: COLONIC IMPLANT
- C: SMALL BOWEL IMPLANT
- D: APPENDIX
- E: RIGHT TUBE AND OVARY
- F: LEFT TUBE AND OVARY
- G: UTERUS AND CERVIX

Gross Description The specimens are received in seven containers of formalin, each labeled with the patient's name. The first container is labeled "omentum." It contains multiple fragments of fibroadipose tissue that weigh 350 grams in toto and measure 20 x 15 x 3.5 cm in aggregate. Most of the fibroadipose tissue fragments contain infiltrative tumor nodules with the largest one measuring 10 x 4 x 3 cm. Sections of the tumor nodules show white-gray solid cut surfaces with focal necrosis.

The second container is labeled "colonic implant" and contains a single fragment of gray-tan soft tissue that measures 6 x 3.5 x 2.0 cm. Sections show white-gray solid cut surface with focal necrosis.

[page 3 of 4]
[REDACTED]

The third container is labeled "small bowel implant." It contains a single fragment of gray-tan soft tissue that measures 1.3 x 1.0 x 0.6 cm. [REDACTED]

The fourth container is labeled "appendix." It contains an appendix that measures 6 cm in length and 0.6 to 0.8 cm in external diameter. The serosal surface of the appendix is focally irregular. Sections show a fecalith measuring 0.7 x 0.5 x 0.5 cm in the appendiceal lumen. No focal lesions are identified. [REDACTED]

The fifth container is labeled "right tube and ovary." It contains an ovary with attached fallopian tube and paraovarian soft tissue, which measure 7 x 4 x 1.3 cm in toto. The ovary measures 3 x 2 x 1.3 cm and has a focally irregular serosal surface. Sectioning of the ovary shows a well-circumscribed, light yellow nodule with a solid cut surface. It measures 1.3 cm in diameter and appears confined to the ovarian parenchyma. The fallopian tube measures 4.8 cm in length and 0.6 cm in external diameter. The serosal surface is congested. Serial cross sections are unremarkable. Focal irregularity is noted in the paratubal/paraovarian soft tissue. Labeled E1 to E3 - sections of the entire right ovary; E4 - right fallopian tube and paratubal/paraovarian soft tissue. [REDACTED]

The sixth container is labeled "left tube and ovary." It contains an ovary with attached fallopian tube and soft tissue, which measure 5.5 x 3.0 x 2.0 cm in toto. The ovary measures 2.7 x 1.5 x 1.3 cm and has a hemorrhagic, focally irregular serosal surface. Sections of the ovary are unremarkable. The fallopian tube measures 3.5 cm in length and 0.7 cm in external diameter. Multiple minute thin-walled cysts are noted on the serosal surface of the fallopian tube. A tumor nodule measuring 2.5 x 1.3 x 1.0 cm is noted on the paratubal/paraovarian soft tissue. Labeled F1 and F2 - sections of the entire left ovary; F3 - left fallopian tube; F4 - tumor nodule in the paratubal/paraovarian soft tissue. [REDACTED]

The seventh container is labeled "uterus and cervix." It contains a simple hysterectomy specimen that measures 6 cm from fundus to cervical os, 4.5 cm from cornu to cornu and 3 cm anterior posteriorly. It weighs 52.6 grams. On the serosal surface of the uterus, there is a focal area with attached irregular, gray-yellow soft tissue that measures 4 x 1.3 x 0.3 cm. In addition, an ill-defined nodule, measuring 2 x 1.5 x 1.0 cm, is attached to the right cornu. The ectocervix measures 3 x 2.5 cm and contains multiple nabothian cysts. It is otherwise unremarkable. The uterus is bivalved at the coronal plane to show a smooth endometrial cavity measuring 2.8 x 0.9 cm. The endocervical canal measures 2.2 x 0.8 cm and is grossly unremarkable. No polyps or focal abnormalities are identified in the endocervical canal or endometrial cavity. The endometrium measures 0.2 to 0.3 cm in thickness and appears cystic. The myometrium measures 1 cm in thickness. A 0.3 cm intramural leiomyoma is identified in the right fundus. Sections are labeled: G1 - anterior cervix; G2 - posterior cervix; G3 - anterior endometrium/myometrium; G4 - posterior endometrium/myometrium; G5 - right fundal leiomyoma; G6 - uterine fundus with attached soft tissue on the serosal surface; G7 - the lesion attached on the right cornu as described above. [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 4b9a2739-9815-45e4-857a-f0061ab56c86 (TCGA-24-1928.DC4407FB-D15B-44D5-9C3B-129CCA67D8F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).